Surgical pathology report (de-identified scan), TCGA case TCGA-XJ-A9DQ, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-XJ-A9DQ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

NAME: _____ SURG PATH #:
MR #: _____ SPECIMEN CLASS:
BILLING #: _____ ALT ID #:
LOCATION: _____ DATE OF PROCEDURE:
AGE: _____ SEX: M DATE RECEIVED:
DOB: _____ TIME RECEIVED:
PHYSICIAN: _____ DATE OF REPORT:
COPY TO: _____ DATE OF PRINTING:

Material Received:

A: Prostate

History:

-year-old male with prostate cancer.

*ICD 3
Adenocarcinoma NOS S140/3
Site: Prostate NOS C61.9
9/26/14*

Final Diagnosis:

A. Prostate, prostatectomy:
Prostatic adenocarcinoma, moderately differentiated, Gleason grade 3+3 (score 6), involving the right lobe with perineural invasion. See comment.

Comment:

Prostate
Procedure: Prostatectomy
Histologic Type: Prostatic adenocarcinoma
Histologic Grade: Moderately differentiated
Gleason Pattern
Primary Pattern: 3
Secondary Pattern: 3
Total Gleason Score (Primary + Secondary): 6
Proportion (percent) of prostate involved by tumor: 5%
Tumor Multicentricity: Present
Extraprostatic Extension: Absent, however very close in two foci
Seminal Vesicle Invasion: Absent
Margins: Free of tumor (within 1 mm of inked margin)
Perineural Invasion: Present
Vascular Invasion: Absent
Additional Pathologic Findings: Stromal hyperplasia
Lymph Nodes: N/A
Pathologic Staging: pT2aNxMx

Primary Tumor (pT)
pT2a: Unilateral, involving one-half of 1 side ("lobe") or less

Regional Lymph Nodes (pN)
pNX: Cannot be assessed

Distant Metastasis (pM)

MR #:

Page 1 of 2

SURGICAL PATHOLOGY REPORT

Date of Printing:

Order Number:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

pMX: Distant metastasis cannot be assessed

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled "prostate" is a radical prostatectomy specimen measuring from 4.2 cm from right to left 3.8 cm from apex to base and 3.0 cm from anterior to posterior. The right seminal vesicle measures 2.2 cm in length and 1.5 cm in diameter. The right vas deferens measures 1.4 cm in length and 0.4 cm in diameter. The left seminal vesicle measures 2.3 cm in length and 1.3 cm in diameter. The left vas deferens measures 1.7 cm in length x 0.4 cm in diameter. The external surface is of the prostate is tan-white and smooth. The right side of the prostate is inked black and the left side is inked blue. The prostate is serially sectioned to reveal a tan-yellow band in the posterior aspect of the prostate that measures 2.5 x 0.8 x 0.5 cm that comes within 0.1 cm of the closest margin. The remainder of the cut-surfaces is tan-pink, smooth and glistening. The specimen is submitted as follows:

- A1 Right bladder neck margin (radially sectioned).
- A2 Left bladder neck margin (radially sectioned).
- A3 Right distal urethral margin (radially sectioned).
- A4 Left distal urethral margins (radially sectioned).
- A5 Right and left seminal vesicles and vas deferens margin
- A6 Section from the right mid-anterior prostate.
- A7 Section from the left mid-anterior prostate.
- A8-A17 Entire posterior right lobe, from apex to base.
- A18-A28 Entire posterior left lobe, from apex to base.

MR #:

Page 2 of 2

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file f1b17d4f-a15b-4e92-92a0-718d120af912 (TCGA-XJ-A9DQ.CAD1C3A1-9EF6-4253-AEEB-C6D80A07C8E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).